Somatic mutation profile of tumor specimen TCGA-VD-A8KL-01A (aliquot TCGA-VD-A8KL-01A-11D-A39W-08) from TCGA case TCGA-VD-A8KL, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 77.9 years (28,450 days).
Specimen TCGA-VD-A8KL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b5bf4f-a3c9-4c76-835e-5ff197fd06eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VD-A8KL-10A (Blood Derived Normal), aliquot TCGA-VD-A8KL-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea06c875-b350-43ab-84a8-3a8cf69cfdd2

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Frame Shift Del 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.79dup p.V27Gfs*42 | Frame Shift Ins (INS) | VAF 115/175 reads (66%) | catalogued as rs397509413; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C1orf127 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs757164639, COSV65438149; called by muse, mutect2, varscan2
- IGFBP3 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs755356224, COSV51871889; called by muse, mutect2, varscan2
- LUZP1 | c.2807C>T p.P936L | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); catalogued as rs1159342358, COSV56505220; called by muse, mutect2
- NRCAM | c.545A>G p.D182G (on ENST00000379028 / NM_001371124.1; = p.D176G on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1367486144; called by muse, mutect2, varscan2
- PAPPA | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs201429158, COSV100075339; called by muse, mutect2, varscan2
- PCDHB7 | c.1665C>A p.N555K | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50753531, COSV99176308; called by muse, mutect2, varscan2
- PDE4DIP | c.5041C>A p.P1681T | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs1553604482; called by muse, mutect2, varscan2
- PRLHR | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs774369942; called by muse, mutect2, varscan2
- RPP38 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562959917; called by muse, mutect2, varscan2
- SLC39A5 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57191982; called by muse, mutect2, varscan2
- DHTKD1 | c.2363_2369del p.F788Wfs*28 | Frame Shift Del (DEL) | VAF 55/98 reads (56%) | called by mutect2, pindel, varscan2
- DYNC2I2 | c.1280_1305del p.P427Qfs*24 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel
- FUBP3 | c.464A>T p.H155L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- GRIN2A | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- PAGR1 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 62/210 reads (30%) | called by muse, mutect2, varscan2
- PRKG1 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3RF1 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, mutect2
- SHROOM2 | c.2605A>G p.R869G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELAPOR2 | c.1875C>T p.H625= (on ENST00000450689 / NM_001142749.3; = p.H458= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- ZNF341 | c.1605G>A p.K535= (on ENST00000375200 / NM_001282935.1; = p.K528= on NM_032819.4) | Silent (SNP) | VAF 30/35 reads (86%) | called by muse, mutect2, varscan2
